Gene-level copy-number profile of tumor specimen TCGA-2A-AAYO-01A from TCGA case TCGA-2A-AAYO, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.0 years (21,183 days).
Specimen TCGA-2A-AAYO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.18ce4a68-d68f-4d24-b4f2-68d421b807e2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2A-AAYO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2df7bde5-4c5a-4db4-a14b-e2d854fd0265

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,673; copy number 2: 56,119; copy number 3: 8; copy number 4: 2; copy number 5: 14; copy number 6: 2; copy number 10: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2A-AAYO-01A-11D-A41J-01): tumor purity 0.73, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:95,917,143–96,015,391, 2 genes, copy number 5 (within-gene range 2–5): AL034348.1, KRT18P50.
- chr6:115,633,540–115,643,916, 1 gene, copy number 6 (within-gene range 2–6): LINC02534.
- chr7:62,275,361–62,275,678, 1 gene, copy number 5: AC128676.1.
- chr8:43,672,823–43,674,591, 2 genes, copy number 10: AC139365.2, AC139365.1.
- chr11:54,591,480–54,725,816, 11 genes, copy number 5: OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.
- chr21:26,889,376–26,939,742, 1 gene, copy number 6 (within-gene range 2–6): AP001599.1.

Autosomal genes at a single copy (total copy number 1): 1,293. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
